Surgical pathology report (de-identified scan), TCGA case TCGA-B6-A40C, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Duke, specimen TCGA-B6-A40C-01A (Primary Tumor).

Patient:

AP Surgical Pathology: Additional Info

Surg Path

CLINICAL HISTORY:

Spiculated mass with pleomorphic calcifications. If invasive carcinoma, please obtain ER, PR, EGFR, HER2/Neu by immunohistochemistry; for all 2+ IHC results please do FISH analysis.

GROSS EXAMINATION:

A. "Left breast, seven cores, with calcifications, 1-2:00 region", in formalin. A 1.5 x 1.0 x 0.3 cm aggregate of multiple core biopsies of pink-tan tissue is entirely submitted in a mesh bag in A1.

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

DIAGNOSIS:

A. "LEFT BREAST, SEVEN CORES, WITH CALCIFICATIONS, 1-2:00 REGION" (STEREOTACTIC NEEDLE CORE BIOPSY):

INVASIVE ADENOCARCINOMA OF THE BREAST.

HISTOLOGIC TYPE: LOBULAR.

NOTTINGHAM COMBINED HISTOLOGIC GRADE: 2 OF 3.

TUBULE FORMATION SCORE: 3.

NUCLEAR PLEOMORPHISM SCORE: 2.

MITOTIC RATE SCORE: 2.

IN-SITU CARCINOMA: PRESENT.

TYPE OF IN-SITU CARCINOMA: LOBULAR (FOCAL DUCTAL FEATURES NOTED).

NUCLEAR GRADE OF IN-SITU CARCINOMA: 1.

MICROCALCIFICATIONS: PRESENT IN ASSOCIATION WITH INVASIVE CARCINOMA.

ESTROGEN/PROGESTERONE RECEPTOR, HER2/NEU, AND EGFR ANALYSIS: PENDING.

PARAFFIN BLOCK NUMBER: A1.

RESULTS WILL BE ISSUED IN A SEPARATE REPORT FROM THE IMAGE CYTOMETRY LAB.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[Redacted Signature]

Electronically signed:

ADDENDUM 1:

Please see tests.

for results of supplementary

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[Redacted Signature]

Electronically signed:

Reviewed/Initials:	[Signature]	

ICD-03

carcinoma, infiltrating lobular NOS
8520/3

Site: breast, NOS C50.9

7-2-12 ro

Source: NCI Genomic Data Commons file c58cd15b-d61c-4bd8-9f98-f23ffc43516d (TCGA-B6-A40C.87B150CC-1C5D-42D5-9951-9157A81316D5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).